Somatic mutation profile of tumor specimen 8e6a9f67-7c53-4386-9ba0-e48101 (aliquot 8e6a9f67-7c53-4386-9ba0-e48101_D6) from CPTAC case 02OV046, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 8e6a9f67-7c53-4386-9ba0-e48101: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a79be37-3135-4478-8753-348f5d3cc9a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen defe3f04-27ab-400d-aeac-bcd160 (Blood Derived Normal), aliquot defe3f04-27ab-400d-aeac-bcd160_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ec7e27e-b647-4845-b407-e7102bd08c08

The open-access MAF lists 122 somatic variants for this specimen: 92 protein-altering or splice-affecting, 13 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 13, Intron 8, Nonsense Mutation 5, Splice Site 5, Frame Shift Del 3, RNA 3, Splice Region 3, 5'UTR 2, 5'Flank 2, 3'UTR 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD36C | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.871); catalogued as rs1382251238; called by muse, mutect2
- ATP2B4 | c.1888A>T p.M630L | Missense Mutation (SNP) | VAF 109/469 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs778690170; called by muse, mutect2, varscan2
- BACH2 | c.509C>G p.T170R | Missense Mutation (SNP) | VAF 182/372 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as COSV57587489; called by muse, mutect2, varscan2
- COPE | c.444-1G>C p.X148_splice | Splice Site (SNP) | VAF 15/108 reads (14%) | catalogued as COSV99447266; called by muse, mutect2, varscan2
- CSNK1E | c.567G>A p.E189= | Splice Region (SNP) | VAF 30/99 reads (30%) | catalogued as rs1569077675; called by muse, mutect2, varscan2
- DENND1C | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 85/123 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as rs375160320; called by muse, mutect2, varscan2
- E2F7 | c.669G>C p.Q223H | Missense Mutation (SNP) | VAF 140/335 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100523931; called by muse, mutect2, varscan2
- EFR3B | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 46/123 reads (37%) | catalogued as rs1228747570, COSV67837971; called by muse, mutect2, varscan2
- ELF4 | c.795G>A p.M265I | Missense Mutation (SNP) | VAF 163/240 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV57451716; called by muse, mutect2, varscan2
- EVX1 | c.126G>T p.M42I | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as rs1371614961; called by muse, mutect2, varscan2
- HMG20A | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100287723; called by muse, mutect2, varscan2
- IRF2BPL | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1420079872; called by muse, mutect2
- KMT2B | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.273); catalogued as rs201268190; called by muse, mutect2, varscan2
- KRTAP5-5 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as rs1226604876, COSV101294201; called by muse, varscan2
- LILRB5 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 206/448 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.035); catalogued as rs765220698, COSV100300233; called by muse, varscan2
- MAN2C1 | c.2173C>T p.Q725* | Nonsense Mutation (SNP) | VAF 68/477 reads (14%) | catalogued as COSV51226383; called by muse, mutect2, varscan2
- MAST2 | c.3627G>C p.K1209N | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); catalogued as COSV63619975; called by muse, varscan2
- MZF1 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.117); catalogued as rs780923513; called by muse, mutect2, varscan2
- NCAM2 | c.132G>T p.A44= | Splice Region (SNP) | VAF 42/102 reads (41%) | catalogued as COSV53086652, COSV53101523; called by muse, mutect2, varscan2
- PARP6 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); catalogued as COSV53004950; called by muse, mutect2, varscan2
- PRPF40B | c.626C>A p.T209N (on ENST00000380281; = p.T203N on NM_012272.3) | Missense Mutation (SNP) | VAF 101/406 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs144272988; called by muse, mutect2, varscan2
- ROS1 | c.5036C>G p.P1679R | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV63851050; called by muse, mutect2, varscan2
- ROS1 | c.5035C>A p.P1679T | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.825); catalogued as COSV63857802; called by muse, mutect2, varscan2
- RP1L1 | c.5107G>T p.G1703W | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99059375; called by muse, mutect2, varscan2
- SCNN1G | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 101/368 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs762732326, COSV55597490; called by muse, mutect2, varscan2
- SPECC1 | c.173C>G p.T58R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV54960933; called by muse, mutect2, varscan2
- VSTM4 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs747822244, COSV104410318; called by muse, mutect2, varscan2
- WRNIP1 | c.1207T>C p.S403P | Missense Mutation (SNP) | VAF 57/392 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.424); catalogued as rs760613951; called by muse, mutect2, varscan2
- ZNF541 | c.1922G>T p.G641V | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.463); catalogued as rs1465971822, COSV54545093; called by muse, mutect2, varscan2
- APOBR | c.978G>C p.E326D | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ARSA | c.194A>C p.Y65S | Missense Mutation (SNP) | VAF 8/236 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATAD3C | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AUH | c.850G>C p.V284L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- C20orf85 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- CA10 | c.836T>C p.F279S | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CARNMT1 | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- CCDC86 | c.588C>A p.S196R | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CD1E | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 98/235 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- CNR2 | c.499C>A p.L167M | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL24A1 | c.3030G>T p.E1010D | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- COL4A3 | c.4717G>T p.G1573C | Missense Mutation (SNP) | VAF 182/413 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CSMD3 | c.9753G>C p.W3251C (on ENST00000297405 / NM_001363185.1; = p.W3082C on NM_052900.3) | Missense Mutation (SNP) | VAF 130/635 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX18 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DSG4 | c.2304C>G p.D768E | Missense Mutation (SNP) | VAF 118/266 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.006); called by mutect2, varscan2
- EFCAB5 | c.1044+2_1044+5del p.X348_splice | Splice Site (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- EHBP1L1 | c.2058_2107del p.P687Dfs*7 | Frame Shift Del (DEL) | VAF 72/290 reads (25%) | called by mutect2, pindel
- EIF2B5 | c.98G>C p.R33T | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- FSD1L | c.21C>A p.C7* | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- IL10RA | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 256/703 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KMT2C | c.12304T>C p.S4102P | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- MGRN1 | c.1656G>C p.E552D | Missense Mutation (SNP) | VAF 5/107 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- MIA3 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 113/320 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MLLT6 | c.2442+8C>T | Splice Region (SNP) | VAF 104/144 reads (72%) | called by muse, mutect2, varscan2
- MPP3 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MXD4 | c.231G>C p.K77N | Missense Mutation (SNP) | VAF 44/347 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- MYBBP1A | c.1566G>C p.Q522H | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NACAD | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 128/300 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, varscan2
- NBPF12 | c.997G>T p.E333* | Nonsense Mutation (SNP) | VAF 57/468 reads (12%) | called by muse, mutect2, varscan2
- NDUFA9 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2
- NOS1 | c.4244C>T p.S1415F | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- NSD2 | c.2881+2T>A p.X961_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- NUDT6 | c.768G>C p.K256N | Missense Mutation (SNP) | VAF 162/204 reads (79%) | SIFT tolerated (0.13); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- PATL2 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PCDH15 | c.3650A>C p.Y1217S | Missense Mutation (SNP) | VAF 12/440 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2
- PGM5 | c.580G>T p.V194L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PKD1L2 | c.1551T>G p.F517L | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PNPLA3 | c.697-1G>A p.X233_splice | Splice Site (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
- PURG | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- RGS14 | c.1700G>T p.*567Lext*163 | Nonstop Mutation (SNP) | VAF 153/190 reads (81%) | called by muse, mutect2, varscan2
- RPL15 | c.593_609del p.L198Pfs*4 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- SALL4 | c.88T>G p.F30V | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- SCN7A | c.3746C>A p.T1249K | Missense Mutation (SNP) | VAF 89/238 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC16A1 | c.1456C>A p.Q486K | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SLC25A33 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 76/105 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A4 | c.667T>A p.S223T (on ENST00000264485 / NM_001098484.3; = p.S179T on NM_003759.4) | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SOGA3 | c.778A>C p.I260L | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SPHKAP | c.2312G>A p.S771N | Missense Mutation (SNP) | VAF 139/333 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SUPT5H | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- TBL1X | c.945_955+10del p.X315_splice | Splice Site (DEL) | VAF 42/173 reads (24%) | called by mutect2, pindel, varscan2
- TBX15 | c.514A>T p.R172* (on ENST00000369429 / NM_001330677.2; = p.R66* on NM_152380.3) | Nonsense Mutation (SNP) | VAF 162/394 reads (41%) | called by muse, mutect2, varscan2
- TCF19 | c.859G>C p.G287R | Missense Mutation (SNP) | VAF 128/303 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- TDRD15 | c.2497G>T p.V833F | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THSD7B | c.308T>A p.L103H | Missense Mutation (SNP) | VAF 214/540 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TNFAIP6 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TP53 | c.722_724del p.S241del | In Frame Del (DEL) | VAF 114/179 reads (64%) | called by mutect2, pindel, varscan2
- UNC13C | c.949A>T p.S317C | Missense Mutation (SNP) | VAF 107/151 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- UQCRHL | c.262A>C p.N88H | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VCAN | c.7705G>C p.E2569Q | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.054); called by muse, mutect2
- WNT1 | c.488C>G p.P163R | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, varscan2
- YEATS2 | c.2461G>C p.G821R | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- ZC3HC1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.795); called by muse, mutect2
- ZFHX2 | c.1867del p.A623Lfs*18 | Frame Shift Del (DEL) | VAF 60/170 reads (35%) | called by mutect2, pindel, varscan2
- CCDC96 | c.1134G>A p.E378= | Silent (SNP) | VAF 65/162 reads (40%) | catalogued as rs1184764599; called by muse, mutect2, varscan2
- CD1D | c.129C>T p.R43= | Silent (SNP) | VAF 78/343 reads (23%) | called by muse, mutect2, varscan2
- CT47B1 | c.636C>T p.A212= | Silent (SNP) | VAF 78/326 reads (24%) | called by muse, mutect2, varscan2
- HMCN1 | c.9126C>A p.G3042= | Silent (SNP) | VAF 65/535 reads (12%) | catalogued as COSV54928978; called by muse, mutect2, varscan2
- MCCC1 | c.2037C>T p.A679= | Silent (SNP) | VAF 35/179 reads (20%) | called by muse, mutect2, varscan2
- OTOGL | c.4320A>C p.P1440= (on ENST00000547103; = p.P1431= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 47/116 reads (41%) | called by muse, mutect2, varscan2
- PPL | c.4965G>C p.R1655= | Silent (SNP) | VAF 79/181 reads (44%) | called by muse, mutect2, varscan2
- PPRC1 | c.270G>A p.L90= | Silent (SNP) | VAF 56/138 reads (41%) | called by muse, mutect2, varscan2
- SAMSN1 | c.489A>T p.P163= | Silent (SNP) | VAF 98/150 reads (65%) | catalogued as COSV53478534; called by muse, mutect2, varscan2
- SMARCA4 | c.4155G>A p.E1385= | Silent (SNP) | VAF 186/530 reads (35%) | called by muse, mutect2, varscan2
- UBA52 | c.372G>A p.K124= | Silent (SNP) | VAF 13/306 reads (4%) | called by muse, mutect2
- VAC14 | c.1209C>T p.V403= | Silent (SNP) | VAF 49/200 reads (25%) | called by muse, mutect2, varscan2
- VWF | c.3819C>T p.S1273= | Silent (SNP) | VAF 121/648 reads (19%) | called by muse, mutect2, varscan2
- ANXA8 | c.207+89C>T | Intron (SNP) | VAF 90/526 reads (17%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+4128C>G | Intron (SNP) | VAF 16/248 reads (6%) | called by muse, mutect2
- ATXN7L1 | c.2472+116T>C | Intron (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- CCDC159 | c.-56G>T | 5'UTR (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- CHRND | chr2:232526143 C>A | 5'Flank (SNP) | VAF 54/278 reads (19%) | catalogued as rs773968785; called by muse, mutect2, varscan2
- DCHS2 | n.5192_5204del | RNA (DEL) | VAF 41/54 reads (76%) | called by mutect2, pindel, varscan2
- FOXP2 | c.*2326_*2327delinsT | 3'UTR (DEL) | VAF 56/247 reads (23%) | called by pindel, varscan2*
- HELZ2 | c.1731-13C>A | Intron (SNP) | VAF 56/179 reads (31%) | catalogued as COSV64409118; called by muse, mutect2, varscan2
- IL20RB | c.89-116A>T | Intron (SNP) | VAF 45/101 reads (45%) | called by muse, mutect2, varscan2
- MIR382 | n.17G>T | RNA (SNP) | VAF 106/420 reads (25%) | called by muse, mutect2, varscan2
- OR51F5P | n.288del | RNA (DEL) | VAF 111/301 reads (37%) | called by mutect2, varscan2
- PUM2 | c.51+996C>T | Intron (SNP) | VAF 42/114 reads (37%) | called by muse, mutect2, varscan2
- RPS18 | c.3+29G>C | Intron (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2, varscan2
- SELENOH | c.122+41C>A | Intron (SNP) | VAF 6/68 reads (9%) | catalogued as rs1357754418; called by muse, mutect2
- SLC29A3 | c.*387T>C | 3'UTR (SNP) | VAF 84/356 reads (24%) | catalogued as rs1360010568; called by muse, mutect2, varscan2
- TGFBR3 | c.-345del | 5'UTR (DEL) | VAF 52/134 reads (39%) | called by mutect2, varscan2
- UBAP1 | chr9:34179025 C>T | 5'Flank (SNP) | VAF 16/16 reads (100%) | called by muse, mutect2, varscan2
